Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A7SH, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A7SH-01A (Primary Tumor).

[page 1 of 3]
(Verified)

A-D. Liver, right lobectomy:

HEPATOCELLULAR CARCINOMA

Tumor number: one

Satellite nodule: no

Location:

Gross type: nodular with perinodular extension

Size(cm): 7.5x6.5x4.0cm

Differentiation: The worst differentiation: Edmondson grade IV

Differentiation: The major differentiation: Edmondson grade III

Histologic type: Macrotrabecular, Microtrabecular, Pseudoglandular

Cell type: Hepatic, Clear

Tumor necrosis: no

Hemorrhage: yes (less than 5 %)

Fatty change: no

Fibrous capsule: partial

Infiltration of capsule: yes

Septum formation: yes

Surgical margin invasion: no(margin of the clearance 5.5 cm)

Serosa invasion: no

Portal vein invasion: no

Bile duct invasion: no

Hepatic vein invasion: no

Hepatic artery invasion: no

Microvessel invasion: yes

Intrahepatic metastasis: no

Multicentric occurrence: no

T stage: pT2

N stage: No metastasis in all 1 lymph node(pN0)

[0/1: periportal vein (0/1)]

ICD-O-3
Carcinoma, hepatocellular, clear
cell type
817413

Site Liver C22.0

9/10/4/13

Non-tumor liver

Chronic hepatitis: yes

Etiology: HBV

Grade, lobular: minimal

Grade, portoperiportal: none

Stage(fibrosis): septal

Cirrhosis: no

Dysplastic nodule: no

[page 2 of 3]
(Verified)

Ductal epithelial dysplasia : no
Other liver disease : no

Gallbladder: No pathologic abnormality
Falciform ligament: No pathologic abnormality

< Immunohistochemical stain results >

Iron (block A11): Negative
Cytokeratin 7 (block A11): Positive in bile ducts
Cytokeratin 19(block A5): Negative
Cytokeratin 7 (block A5): Focal positive
Hepatocyte (block A5): Positive

- A. The specimen received in formalin consists of a lobectomy of liver, measuring 16x12x8cm and weighing 800gm. The external surface shows a huge capsular mass. The parenchyme resection margins are clear. The vascular resection margin also clear. On section, there is an nodular mass with perinodular extension, measuring 7.5x6.5x4cm. The mass is 5.5cm apart from parenchyme resection margin. The remaining parenchyme shows cirrhotic change. Representative sections are embedded. (A1- Periportal vain lymph node, A2 to 8- tumor one plane, A9 and 10- tumor with capsule, A11- background liver)
- B. The specimen received in formalin consists of a gallbladder, measuring 8cm in length and 3cm in diameter. The capsular surface is unremarkable. The wall measures 0.2cm in maximal thickness. The mucosa is greenish velvety. There is no stone or polyp. Representative sections are embedded in one cassette.
- C. The specimen received in formalin consists of compartmentalized lymph nodes. All lymph nodes found are entirely embedded. (C-LN)
- D. The specimen received in formalin consists of a lump of adipose tissue, clinically labeled as "falciform ligament", measuring 4x3x1cm. On serial section, there is no definite mass. Representative sections are embedded in a cassette.

H&E(14), MT(1), RTC(1), D-PAS(1), Iron(1), Cytokeratin 7(7), Cytokeratin 19(1),
Iron (1)

[page 3 of 3]
(Verified)

OK
to process

Criteria	HW 9/24/15	Yes	No

Source: NCI Genomic Data Commons file 49effc19-cb96-4948-a612-16225aecfd8c (TCGA-RC-A7SH.F862582D-03E2-41AB-85C8-B637C2573E74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).